Somatic mutation profile of tumor specimen 1de8d3d8-fc0e-4be0-8aa7-127c7b (aliquot 1de8d3d8-fc0e-4be0-8aa7-127c7b_D6_1) from CPTAC case 13OV004, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 1de8d3d8-fc0e-4be0-8aa7-127c7b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26e8a202-3696-4804-b31b-65e6755f9d32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5d6c64a7-34f3-416b-aa85-e01e9e (Blood Derived Normal), aliquot 5d6c64a7-34f3-416b-aa85-e01e9e_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6fb5e3-b03e-421f-a466-44649ad14f3e

The open-access MAF lists 161 somatic variants for this specimen: 108 protein-altering or splice-affecting, 32 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 32, Intron 11, Frame Shift Del 7, In Frame Del 5, Nonsense Mutation 5, 3'UTR 4, Splice Site 4, Splice Region 3, RNA 3, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as rs749384178; called by muse, mutect2, varscan2
- CCR5 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as COSV52753142; called by muse, mutect2, varscan2
- CELF4 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs1429263627; called by muse, mutect2, varscan2
- EML1 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376629514, COSV99214370, COSV99215314; called by muse, mutect2, varscan2
- ESPNL | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 182/1289 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as rs1460442150; called by muse, mutect2, varscan2
- FOSL2 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV53104041; called by muse, mutect2, varscan2
- GLRA2 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54342039; called by muse, mutect2
- GPATCH1 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 45/175 reads (26%) | catalogued as rs1175557455; called by muse, mutect2, varscan2
- GPRIN1 | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV99991650; called by muse, mutect2
- IDI2 | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1266573166; called by muse, mutect2, varscan2
- KCNK2 | c.808G>T p.G270C (on ENST00000444842 / NM_001017425.3; = p.G255C on NM_014217.4) | Missense Mutation (SNP) | VAF 80/122 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101221849; called by muse, mutect2, varscan2
- LAMA2 | c.7134G>A p.M2378I | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV101370504; called by muse, mutect2
- LRCH1 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV60852128; called by muse, mutect2, varscan2
- MPEG1 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551486642, COSV57091207; called by muse, mutect2, varscan2
- MRGPRX4 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 162/257 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58590025; called by muse, varscan2
- OR2A14 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 244/628 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs201108825; called by muse, mutect2, varscan2
- OR5AU1 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 348/441 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976328746; called by muse, mutect2, varscan2
- OR5B21 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 175/385 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64481625; called by muse, mutect2, varscan2
- PHKA2 | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 176/518 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1238366668; called by muse, mutect2, varscan2
- PTPRM | c.4187G>T p.S1396I | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59843482; called by muse, mutect2, varscan2
- SEMA4F | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV60284358; called by muse, mutect2, varscan2
- SHOX | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100479103, COSV99061053; called by muse, mutect2, varscan2
- SPTA1 | c.4420C>G p.R1474G | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs368042757, COSV63752884; called by muse, mutect2, varscan2
- ST8SIA1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1317393088, COSV53956461; called by muse, mutect2, varscan2
- TRPA1 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51563807; called by muse, mutect2, varscan2
- USF2 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55885788; called by muse, mutect2
- ADA | c.975+2T>C p.X325_splice | Splice Site (SNP) | VAF 155/440 reads (35%) | called by muse, mutect2, varscan2
- ADARB2 | c.1508C>T p.T503I | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGRN | c.5233dup p.R1745Pfs*126 | Frame Shift Ins (INS) | VAF 89/543 reads (16%) | called by mutect2, pindel, varscan2
- ANGPT1 | c.1146_1184del p.R384_N396del | In Frame Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- ASB2 | c.178_216del p.P60_A72del | In Frame Del (DEL) | VAF 79/159 reads (50%) | called by mutect2, pindel, varscan2
- AVPR1A | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 375/596 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BABAM1 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BMP15 | c.1046A>T p.D349V | Missense Mutation (SNP) | VAF 125/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC14 | c.604C>T p.H202Y (on ENST00000488653; = p.H154Y on NM_022757.5) | Missense Mutation (SNP) | VAF 167/224 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CCNB3 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CCNYL1 | c.889G>C p.D297H (on ENST00000295414 / NM_001330218.2; = p.D227H on NM_152523.2) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC37 | c.103-2A>T p.X35_splice | Splice Site (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- CEBPE | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 251/1301 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CFTR | c.273+7A>G | Splice Region (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- CFTR | c.3562_3606del p.S1188_D1202del | In Frame Del (DEL) | VAF 60/283 reads (21%) | called by mutect2, pindel
- CHTOP | c.491G>C p.R164T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- COL13A1 | c.800G>T p.S267I (on ENST00000398978 / NM_001130103.2; = p.S210I on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- COL16A1 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 125/203 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- COL26A1 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 133/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRISPLD2 | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRMP1 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSKMT | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CUBN | c.4723_4745del p.S1575Kfs*6 | Frame Shift Del (DEL) | VAF 170/473 reads (36%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- DIPK1C | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 139/222 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- DNAH17 | c.6778G>C p.G2260R | Missense Mutation (SNP) | VAF 105/162 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.2639G>C p.S880T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DST | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DTNA | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- EDN3 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- EML6 | c.5328C>T p.I1776= | Splice Region (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- FAM124A | c.241G>T p.V81L (on ENST00000322475 / NM_001242312.2; = p.V117L on NM_145019.4) | Missense Mutation (SNP) | VAF 110/167 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM71F2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FLNB | c.4741_4754del p.I1581Wfs*12 | Frame Shift Del (DEL) | VAF 54/210 reads (26%) | called by mutect2, pindel, varscan2
- GATA6 | c.1136-14_1162del p.X379_splice | Splice Site (DEL) | VAF 32/238 reads (13%) | called by mutect2, pindel
- GML | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSX1 | c.553_558del p.N185_L186del | In Frame Del (DEL) | VAF 95/170 reads (56%) | called by pindel, varscan2
- HOXA5 | c.591G>T p.R197S | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITCH | c.2257C>T p.Q753* (on ENST00000262650 / NM_001257137.3; = p.Q712* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- ITGA7 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 478/784 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- ITGAM | c.3015G>T p.L1005F (on ENST00000648685 / NM_001145808.2; = p.L1004F on NM_000632.4) | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAGN1 | c.518G>T p.W173L | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- JPH3 | c.1228C>G p.R410G | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- KCNU1 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- LAT | c.644-4A>G | Splice Region (SNP) | VAF 126/316 reads (40%) | called by muse, mutect2, varscan2
- MAML2 | c.194_211del p.S65_E71delinsK | In Frame Del (DEL) | VAF 531/1023 reads (52%) | called by mutect2, pindel, varscan2
- MED14 | c.3034C>G p.Q1012E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MTIF2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- MUC1 | c.2798C>G p.P933R (on ENST00000611571 / NM_001371720.1; = p.P146R on NM_001204285.2) | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, varscan2
- MUC5B | c.5209T>A p.S1737T | Missense Mutation (SNP) | VAF 194/299 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYO5A | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NHLH1 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR52H1 | c.149T>A p.L50H (on ENST00000322653; = p.L56H on NM_001005289.1) | Missense Mutation (SNP) | VAF 205/321 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC3 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 14/473 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2
- PARP11 | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PDE6C | c.2299A>C p.N767H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PDHX | c.1132A>C p.I378L | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PGR | c.1925_1934dup p.R646Qfs*2 | Nonsense Mutation (INS) | VAF 104/194 reads (54%) | called by mutect2, varscan2
- PLA2G15 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 161/238 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PPP2R1B | c.1052A>C p.Q351P | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM2 | c.2879A>C p.Q960P | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD3 | c.192_222del p.Q64Hfs*46 | Frame Shift Del (DEL) | VAF 73/263 reads (28%) | called by mutect2, pindel, varscan2
- RFPL1 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- RP2 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 188/589 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRAGD | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SAG | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD7 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEMA3D | c.862-2A>G p.X288_splice | Splice Site (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- SIX5 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 117/167 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A5 | c.2357T>C p.L786P (on ENST00000454036 / NM_001134771.2; = p.L763P on NM_020708.5) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC1A6 | c.1436_1479del p.V479Dfs*8 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel, varscan2
- SLC6A16 | c.1722C>G p.I574M | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPATA31A6 | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.047); called by mutect2, varscan2
- SRXN1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 140/620 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRIP1 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 152/416 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- TOX2 | c.564_583del p.Q188Hfs*60 (on ENST00000358131 / NM_001098798.2; = p.Q137Hfs*60 on NM_032883.3) | Frame Shift Del (DEL) | VAF 47/202 reads (23%) | called by mutect2, pindel, varscan2
- TP53 | c.256del p.A86Hfs*37 | Frame Shift Del (DEL) | VAF 217/375 reads (58%) | called by mutect2, pindel, varscan2
- WNK1 | c.6151A>T p.S2051C (on ENST00000315939 / NM_018979.4; = p.S1803C on NM_014823.3) | Missense Mutation (SNP) | VAF 190/232 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZDBF2 | c.4149del p.K1383Nfs*6 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | called by mutect2, pindel, varscan2
- ZEB2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZIC1 | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 156/588 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF491 | c.705G>C p.R235S | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ADCK2 | c.402T>A p.L134= | Silent (SNP) | VAF 86/214 reads (40%) | called by muse, mutect2, varscan2
- ANKFN1 | c.3351C>T p.A1117= (on ENST00000653862; = p.A970= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 234/384 reads (61%) | catalogued as rs1242962239, COSV73718992; called by muse, mutect2, varscan2
- ARHGEF40 | c.2826G>A p.Q942= | Silent (SNP) | VAF 268/363 reads (74%) | called by muse, mutect2, varscan2
- CACNG3 | c.456C>G p.G152= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- CCHCR1 | c.969G>A p.E323= | Silent (SNP) | VAF 86/204 reads (42%) | called by muse, mutect2, varscan2
- CDC42EP1 | c.915G>A p.V305= | Silent (SNP) | VAF 108/176 reads (61%) | called by muse, mutect2, varscan2
- CHGB | c.1053C>A p.V351= | Silent (SNP) | VAF 100/378 reads (26%) | called by muse, mutect2
- CHMP4B | c.498G>A p.A166= | Silent (SNP) | VAF 238/700 reads (34%) | catalogued as rs370101047, COSV54134941; called by muse, mutect2, varscan2
- CSMD3 | c.8178C>T p.D2726= | Silent (SNP) | VAF 193/499 reads (39%) | called by muse, mutect2, varscan2
- GNAQ | c.747G>A p.E249= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- GPR162 | c.540C>A p.G180= | Silent (SNP) | VAF 80/334 reads (24%) | called by muse, mutect2, varscan2
- HYDIN | c.8481C>T p.Y2827= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs1351844184; called by muse, mutect2, varscan2
- IL36B | c.441G>A p.K147= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs746077689; called by muse, mutect2, varscan2
- INPPL1 | c.2550A>G p.Q850= | Silent (SNP) | VAF 159/607 reads (26%) | catalogued as rs1157099238; called by muse, mutect2, varscan2
- MDGA1 | c.225G>A p.T75= | Silent (SNP) | VAF 73/222 reads (33%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.567G>A p.V189= | Silent (SNP) | VAF 162/256 reads (63%) | called by muse, varscan2
- NPHS2 | c.201G>A p.V67= | Silent (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
- NR4A3 | c.1266T>G p.T422= | Silent (SNP) | VAF 85/215 reads (40%) | called by muse, mutect2, varscan2
- OR9Q2 | c.489C>A p.A163= | Silent (SNP) | VAF 232/776 reads (30%) | called by muse, mutect2
- PIM3 | c.459G>A p.Q153= | Silent (SNP) | VAF 222/343 reads (65%) | called by muse, mutect2, varscan2
- PLA2G2E | c.423C>A p.P141= | Silent (SNP) | VAF 109/292 reads (37%) | called by muse, mutect2, varscan2
- SIGLEC16 | c.705T>A p.T235= | Silent (SNP) | VAF 90/224 reads (40%) | called by muse, mutect2, varscan2
- SLC1A3 | c.171T>C p.A57= | Silent (SNP) | VAF 46/241 reads (19%) | called by muse, mutect2, varscan2
- SLC5A11 | c.823C>T p.L275= | Silent (SNP) | VAF 77/236 reads (33%) | catalogued as COSV100762773; called by muse, mutect2, varscan2
- SYF2 | c.660G>A p.K220= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1453551655; called by muse, mutect2, varscan2
- TGFBI | c.1965A>G p.K655= | Silent (SNP) | VAF 229/396 reads (58%) | catalogued as rs970788091; called by muse, mutect2, varscan2
- TRIP10 | c.444A>G p.A148= | Silent (SNP) | VAF 97/246 reads (39%) | called by muse, mutect2, varscan2
- UBE2E2 | c.288A>G p.G96= | Silent (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- UBR5 | c.573A>T p.S191= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- VPS35L | c.1623T>C p.D541= | Silent (SNP) | VAF 74/320 reads (23%) | called by muse, mutect2, varscan2
- WSCD1 | c.171G>A p.V57= | Silent (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- ZFP92 | c.756G>T p.L252= | Silent (SNP) | VAF 161/252 reads (64%) | called by muse, mutect2, varscan2
- ABCC10 | c.3959+59G>C | Intron (SNP) | VAF 163/379 reads (43%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793852 C>T | 3'Flank (SNP) | VAF 8/110 reads (7%) | catalogued as rs1024268537; called by muse, mutect2
- AC103993.1 | n.96del | RNA (DEL) | VAF 41/213 reads (19%) | called by mutect2, pindel, varscan2
- ACER3 | c.267+73C>G | Intron (SNP) | VAF 38/245 reads (16%) | called by muse, mutect2, varscan2
- AKT2 | c.-85+9761C>T | Intron (SNP) | VAF 55/87 reads (63%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811971 C>A | 3'Flank (SNP) | VAF 88/267 reads (33%) | catalogued as rs537678245; called by muse, mutect2, varscan2
- CORO6 | c.-59G>C | 5'UTR (SNP) | VAF 49/79 reads (62%) | called by muse, mutect2, varscan2
- DENND6B | c.178-48_178-12del | Intron (DEL) | VAF 83/276 reads (30%) | called by mutect2, pindel, varscan2
- DNAJC6 | c.22+44803_22+44814del | Intron (DEL) | VAF 12/37 reads (32%) | called by mutect2, varscan2
- HLA-F | c.*9C>T | 3'UTR (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.504T>A | RNA (SNP) | VAF 13/238 reads (5%) | called by muse, mutect2
- HOXA11 | c.*1G>A | 3'UTR (SNP) | VAF 145/260 reads (56%) | called by mutect2, varscan2
- IL20RB | c.88+11094C>T | Intron (SNP) | VAF 14/34 reads (41%) | catalogued as rs1284250083; called by muse, mutect2, varscan2
- MCM5 | c.753-35C>T | Intron (SNP) | VAF 149/453 reads (33%) | called by muse, mutect2, varscan2
- RPSA | c.-34+132C>G | Intron (SNP) | VAF 56/173 reads (32%) | called by muse, mutect2, varscan2
- SLC22A9 | c.*2G>C | 3'UTR (SNP) | VAF 25/92 reads (27%) | catalogued as COSV54167304; called by muse, mutect2, varscan2
- TMEM71 | c.752+26G>T | Intron (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- TTC6 | c.358-1292T>C | Intron (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- UBBP4 | n.848G>T | RNA (SNP) | VAF 119/252 reads (47%) | called by muse, mutect2, varscan2
- UHRF1 | c.-10-1352C>T | Intron (SNP) | VAF 60/100 reads (60%) | catalogued as rs1420285651; called by muse, mutect2, varscan2
- VNN3 | c.*315G>T | 3'UTR (SNP) | VAF 156/246 reads (63%) | catalogued as rs773373514; called by muse, mutect2
